Somatic mutation profile of tumor specimen ALCH-B35E-TTP1-A (aliquot ALCH-B35E-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B35E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.2 years (29,299 days).
Specimen ALCH-B35E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6f01e36-ff82-4207-a53f-2cdbaf6b6cdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B35E-NB1-A (Blood Derived Normal), aliquot ALCH-B35E-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbed773d-aaff-4cc4-8c8a-32e358dd79c5

The open-access MAF lists 70 somatic variants for this specimen: 41 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 22, Intron 6, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3041G>T p.G1014V | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1486124584; called by muse, mutect2
- CDH8 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV100184083, COSV54847158; called by muse, mutect2
- COL1A2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.92); catalogued as COSV51963302; called by muse, mutect2
- FAM199X | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs894490132; called by muse, mutect2
- HCAR3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.115); catalogued as COSV63674006; called by muse, mutect2
- KDM5B | c.516A>T p.R172S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99350135; called by muse, mutect2
- KDM5B | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52509923; called by muse, mutect2
- PKHD1 | c.3418G>T p.D1140Y | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100584073; called by muse, mutect2
- PLEKHA7 | c.3323A>G p.Y1108C | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.453); catalogued as rs1180667440; called by muse, mutect2
- PRDM6 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 25/530 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs1217988496; called by muse, mutect2
- SOAT2 | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1489939165, COSV56858768; called by muse, mutect2
- TRAPPC12 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100160895, COSV60848827; called by muse, mutect2
- VASH1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99388309; called by muse, mutect2
- ZFPM2 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1478934899, COSV65872970; called by muse, mutect2
- AKAP4 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C5orf22 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2
- CDC42BPG | c.1411T>C p.S471P | Missense Mutation (SNP) | VAF 19/411 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CNTLN | c.3716C>G p.S1239C | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- DOC2A | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 36/892 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- DUOX2 | c.3798C>G p.S1266R | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2
- GGA2 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRID2IP | c.2788G>C p.E930Q | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- HUWE1 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- IGSF1 | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.018); called by mutect2, varscan2
- IPO5 | c.2650G>A p.G884R | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KCNN1 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.109); called by muse, mutect2
- LIN28A | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP1B | c.4327G>C p.D1443H | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2L5 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2
- PKD1 | c.8399C>T p.P2800L | Missense Mutation (SNP) | VAF 46/1057 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- PKDREJ | c.5645C>A p.A1882E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- PNCK | c.538+1G>C p.X180_splice (on ENST00000340888 / NM_001366975.1; = p.X263_splice on NM_001039582.3) | Splice Site (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- POM121L2 | c.2399T>C p.L800P | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); called by muse, mutect2
- PXDN | c.4126C>A p.R1376S | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF152 | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SERAC1 | c.1311A>C p.T437= | Splice Region (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- TK2 | c.510C>G p.F170L (on ENST00000299697; = p.F226L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2
- TRIO | c.8284G>T p.V2762F | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VPS13C | c.9097C>G p.L3033V (on ENST00000644861 / NM_020821.3; = p.L2990V on NM_017684.5) | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZFR | c.2668C>G p.P890A | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF619 | c.659A>T p.E220V | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- BRINP2 | c.1687C>T p.L563= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- CACNA1I | c.6150G>A p.A2050= | Silent (SNP) | VAF 28/304 reads (9%) | catalogued as rs1313894195; called by muse, mutect2
- CADM3 | c.352C>A p.R118= (on ENST00000368125 / NM_001127173.3; = p.R152= on NM_021189.5) | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs983781182, COSV63685158; called by muse, mutect2
- CATSPER1 | c.1509C>T p.G503= | Silent (SNP) | VAF 21/725 reads (3%) | catalogued as rs1182811230; called by muse, mutect2
- CNOT4 | c.1416G>A p.L472= (on ENST00000315544 / NM_001190848.1; = p.L469= on NM_013316.4) | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- ECI1 | c.240C>T p.I80= | Silent (SNP) | VAF 28/748 reads (4%) | called by muse, mutect2
- ENGASE | c.1794C>G p.T598= | Silent (SNP) | VAF 27/584 reads (5%) | called by muse, mutect2
- FAM47C | c.840T>A p.S280= | Silent (SNP) | VAF 19/590 reads (3%) | called by muse, mutect2
- INCENP | c.510G>A p.E170= | Silent (SNP) | VAF 22/536 reads (4%) | called by muse, mutect2
- KCND1 | c.1689A>T p.A563= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- METTL27 | c.57G>C p.A19= | Silent (SNP) | VAF 18/297 reads (6%) | called by muse, mutect2
- NLRX1 | c.1116C>G p.S372= | Silent (SNP) | VAF 31/708 reads (4%) | called by muse, mutect2
- PRAMEF15 | c.1188C>A p.T396= | Silent (SNP) | VAF 27/676 reads (4%) | called by muse, mutect2
- RBMXL2 | c.705C>A p.P235= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as rs772189905; called by muse, mutect2
- SLC1A7 | c.894C>A p.V298= | Silent (SNP) | VAF 40/726 reads (6%) | called by muse, mutect2
- SLC35G3 | c.279C>A p.P93= | Silent (SNP) | VAF 43/723 reads (6%) | called by muse, mutect2
- SLITRK4 | c.429C>A p.I143= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs1556428051; called by muse, mutect2, varscan2
- SREBF2 | c.2586C>T p.S862= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as rs1405619501; called by muse, mutect2
- SUCLG1 | c.63C>T p.L21= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as rs982734922, COSV67265520, COSV67265626; called by muse, mutect2
- TLN2 | c.6762C>T p.H2254= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs140658126; called by muse, mutect2, varscan2
- TUBGCP6 | c.2160C>T p.R720= | Silent (SNP) | VAF 26/307 reads (8%) | catalogued as COSV99955099; called by muse, mutect2
- XYLT1 | c.1494G>A p.L498= | Silent (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- ADD3-AS1 | chr10:109942752 C>T | 3'Flank (SNP) | VAF 12/343 reads (3%) | called by muse, mutect2
- FLYWCH1 | c.1514-510C>T | Intron (SNP) | VAF 15/391 reads (4%) | catalogued as rs911022472; called by muse, mutect2
- NEU1 | c.352+26C>G | Intron (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- STAP2 | c.1073-132A>C | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs1263422571, COSV55696905; called by mutect2, varscan2
- UGT1A6 | c.862-23403G>T | Intron (SNP) | VAF 20/540 reads (4%) | catalogued as rs1346320649; called by muse, mutect2
- VRK1 | c.484-45G>C | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- ZRSR2 | c.203+1536A>C | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1199400991; called by muse, mutect2
